Somatic mutation profile of tumor specimen TARGET-10-PATAYT-09A (aliquot TARGET-10-PATAYT-09A-01D) from TARGET case TARGET-10-PATAYT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,158 days).
Specimen TARGET-10-PATAYT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43c660dd-5ffb-499f-8d9a-cdd5f18acbe0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATAYT-10B (Blood Derived Normal), aliquot TARGET-10-PATAYT-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baa20ae1-2a68-4d7a-8243-c2bfbf77ccc6

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 3, 5'UTR 3, 3'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121912874, CM930162, COSV61536227; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOBEC3F | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs377716039; called by muse, mutect2, varscan2
- CREB3L1 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199553915, COSV55833842; called by muse, mutect2, varscan2
- NOTCH1 | c.7529T>A p.L2510H | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53030748, COSV53108316; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- NYAP2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as rs761168029, COSV56001990; called by muse, mutect2, varscan2
- OR5T1 | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57305436; called by muse, mutect2, varscan2
- PREPL | c.2035A>G p.N679D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV53220295; called by muse, mutect2, varscan2
- SRRM1 | c.2681C>A p.S894* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV60481838; called by mutect2, varscan2
- STAB2 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs759885088, COSV66349548; called by muse, mutect2, varscan2
- TRIO | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1311719411, COSV60091843, COSV60101515; called by muse, mutect2
- TRPC5 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs962685683, COSV53303315; called by muse, mutect2, varscan2
- URGCP | c.2053C>T p.R685* (on ENST00000453200 / NM_001077663.3; = p.R676* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 17/144 reads (12%) | catalogued as rs776220574, COSV56251597; called by muse, mutect2, varscan2
- ADAMTS12 | c.195T>A p.H65Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.158); called by muse, mutect2
- H3C11 | c.238_239insGGGGTTA p.K80Rfs*3 | Nonsense Mutation (INS) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- MACROD2 | c.912C>A p.S304R (on ENST00000642719; = p.S276R on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NOTCH1 | c.7366delinsCCATATTCT p.I2456Pfs*24 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | called by pindel, varscan2*
- CDH13 | c.237C>T p.G79= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs764913956, COSV51862955; called by muse, mutect2
- ESPN | c.2166C>T p.P722= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs754894303, COSV100911552; called by muse, varscan2
- PCDH17 | c.2394C>T p.F798= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV64971619; called by muse, mutect2, varscan2
- CAMK2B | c.1340-153dup | Intron (INS) | VAF 8/24 reads (33%) | catalogued as rs760263712; called by mutect2, varscan2
- EXOSC9 | c.-54G>A | 5'UTR (SNP) | VAF 32/49 reads (65%) | called by muse, mutect2, varscan2
- NRXN3 | c.-52C>T | 5'UTR (SNP) | VAF 12/29 reads (41%) | catalogued as COSV101626842; called by muse, mutect2, varscan2
- OCIAD1 | c.*151T>A | 3'UTR (SNP) | VAF 14/31 reads (45%) | catalogued as rs1458964475; called by muse, mutect2, varscan2
- SPAG17 | c.-66G>A | 5'UTR (SNP) | VAF 4/19 reads (21%) | catalogued as rs1399787710; called by muse, mutect2
